Somatic mutation profile of tumor specimen TCGA-67-3770-01A (aliquot TCGA-67-3770-01A-01D-0969-08) from TCGA case TCGA-67-3770, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.2 years (25,658 days).
Specimen TCGA-67-3770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f6aba9b1-3310-4e09-b3c4-4b336740596b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-67-3770-10A (Blood Derived Normal), aliquot TCGA-67-3770-10A-01D-0969-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2d5187b-f6a7-47c9-b9b8-fd99d5879d1a

The open-access MAF lists 240 somatic variants for this specimen: 176 protein-altering or splice-affecting, 55 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 153, Silent 55, Nonsense Mutation 9, Splice Site 5, Frame Shift Del 4, Intron 3, RNA 3, Splice Region 2, Frame Shift Ins 2, 5'UTR 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 83/326 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.461G>T p.G154V | Missense Mutation (SNP) | VAF 52/123 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762846821, CM951223, COSV52667239, COSV52783646, COSV53625267; called by muse, mutect2, varscan2
- AC244197.3 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs782543505, COSV61711429; called by muse, mutect2, varscan2
- ADCK2 | c.1273G>C p.A425P | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50780791; called by muse, mutect2, varscan2
- ADGRE1 | c.2344A>T p.S782C | Missense Mutation (SNP) | VAF 54/249 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV51672684; called by muse, mutect2, varscan2
- ADGRG2 | c.1237C>A p.P413T (on ENST00000379869 / NM_001079858.3; = p.P410T on NM_005756.4) | Missense Mutation (SNP) | VAF 152/473 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.03); catalogued as COSV61337766; called by muse, mutect2, varscan2
- ADGRV1 | c.562G>T p.E188* | Nonsense Mutation (SNP) | VAF 19/32 reads (59%) | catalogued as COSV67979447; called by muse, mutect2, varscan2
- AGMO | c.90C>G p.F30L | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV61106796; called by muse, mutect2, varscan2
- AHRR | c.181C>G p.L61V | Missense Mutation (SNP) | VAF 95/345 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57083115, COSV57090941; called by muse, mutect2, varscan2
- AIFM1 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 282/867 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as rs750418813, COSV54852416; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.4492A>G p.I1498V | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62339896; called by muse, mutect2, varscan2
- ALDH8A1 | c.1127C>T p.T376M | Missense Mutation (SNP) | VAF 47/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774809603, COSV55640438; called by muse, mutect2, varscan2
- ALS2 | c.2805G>T p.W935C | Missense Mutation (SNP) | VAF 184/313 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51884423; called by muse, mutect2, varscan2
- ALS2 | c.2006A>G p.Y669C | Missense Mutation (SNP) | VAF 50/81 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51884436; called by muse, mutect2, varscan2
- ANKS1B | c.1492A>C p.S498R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.638); catalogued as COSV61337087; called by muse, mutect2, varscan2
- ARHGAP25 | c.574G>T p.G192C (on ENST00000409202 / NM_001007231.3; = p.G184C on NM_014882.3) | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54899059, COSV54909603; called by muse, mutect2, varscan2
- ARL5B | c.38G>T p.C13F | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV66010949; called by muse, mutect2, varscan2
- ASPA | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV53980179; called by muse, mutect2, varscan2
- ASPM | c.2173G>T p.V725L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV54125610; called by muse, mutect2, varscan2
- B4GALNT1 | c.689A>G p.Y230C | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as COSV57541504; called by muse, mutect2, varscan2
- BCL11B | c.1490C>T p.S497F (on ENST00000357195 / NM_001282237.2; = p.S426F on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs770419592, COSV61733771; called by muse, varscan2
- BPI | c.1381C>A p.P461T (on ENST00000262865; = p.P457T on NM_001725.3) | Missense Mutation (SNP) | VAF 81/199 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.463); catalogued as COSV53404145; called by muse, mutect2, varscan2
- BTK | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 154/497 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58117681; called by muse, mutect2, varscan2
- CCER1 | c.476C>A p.P159Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.015); catalogued as rs1053185578, COSV62646074, COSV62647724; called by muse, mutect2, varscan2
- CD1C | c.623C>A p.A208D | Missense Mutation (SNP) | VAF 26/144 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV63805781; called by muse, mutect2
- CDC42BPA | c.3709G>C p.D1237H (on ENST00000334218 / NM_001366019.2; = p.D1224H on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62003766; called by muse, mutect2, varscan2
- CDH12 | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 41/204 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66390334; called by muse, mutect2, varscan2
- CELF2 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.007); catalogued as COSV64927774; called by muse, mutect2, varscan2
- CMKLR1 | c.320T>C p.F107S (on ENST00000312143 / NM_001142344.2; = p.F105S on NM_004072.3) | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56436566; called by muse, mutect2, varscan2
- CNTN6 | c.2520C>A p.V840= | Splice Region (SNP) | VAF 13/100 reads (13%) | catalogued as COSV63163479; called by muse, mutect2, varscan2
- COL4A1 | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.461); catalogued as COSV65422129; called by muse, mutect2, varscan2
- COQ7 | c.394G>T p.E132* | Nonsense Mutation (SNP) | VAF 38/300 reads (13%) | catalogued as COSV58981337; called by muse, mutect2, varscan2
- CSMD3 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.368); catalogued as COSV52113654; called by muse, mutect2, varscan2
- CYP4F22 | c.721G>T p.V241F | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.77); catalogued as COSV54106888; called by muse, mutect2, varscan2
- DBX1 | c.964C>A p.P322T | Missense Mutation (SNP) | VAF 106/343 reads (31%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.02); catalogued as COSV57053600; called by muse, mutect2, varscan2
- DMGDH | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772215706, COSV54861015; called by muse, mutect2, varscan2
- DNAH7 | c.11271G>T p.L3757F | Missense Mutation (SNP) | VAF 207/347 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56753895; called by muse, mutect2, varscan2
- ELAVL2 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56358068, COSV56371535; called by muse, mutect2, varscan2
- EOLA2 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 93/381 reads (24%) | catalogued as COSV62207032; called by muse, mutect2, varscan2
- EP400 | c.4901G>T p.R1634L | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57764487; called by muse, mutect2, varscan2
- EPB41L4B | c.847G>T p.D283Y | Missense Mutation (SNP) | VAF 46/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65795749; called by muse, mutect2, varscan2
- EPX | c.132G>C p.K44N | Missense Mutation (SNP) | VAF 125/428 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772930951, COSV56595235; called by muse, mutect2, varscan2
- EXOSC7 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 61/177 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55555557, COSV99651746; called by muse, mutect2, varscan2
- FAM110A | c.222G>T p.Q74H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV55726778; called by muse, mutect2
- FAM71A | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV54234778; called by muse, mutect2, varscan2
- FAT3 | c.5760C>G p.Y1920* | Nonsense Mutation (SNP) | VAF 23/73 reads (32%) | catalogued as COSV53081309; called by muse, mutect2, varscan2
- FLT3LG | c.635G>A p.R212Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs375362082; called by muse, mutect2
- GABBR2 | c.876G>T p.Q292H | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.446); catalogued as COSV52294711; called by muse, mutect2, varscan2
- GABRA5 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV59476292; called by muse, mutect2, varscan2
- GALNTL5 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as COSV67179419; called by muse, mutect2, varscan2
- GHRHR | c.680T>A p.L227Q | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV58195710; called by muse, mutect2, varscan2
- GLI2 | c.4059G>T p.Q1353H (on ENST00000361492 / NM_001374353.1; = p.Q1370H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV58035680, COSV58051986; called by muse, mutect2, varscan2
- GPR142 | c.1126G>C p.V376L | Missense Mutation (SNP) | VAF 125/374 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV59518721, COSV59519491, COSV99046011; called by muse, mutect2, varscan2
- GRAMD1A | c.115A>G p.T39A | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58765999; called by muse, mutect2, varscan2
- HEPH | c.1894C>T p.P632S (on ENST00000343002; = p.P365S on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV57959928; called by muse, mutect2, varscan2
- HS1BP3 | c.749C>A p.P250Q | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV58312088; called by muse, varscan2
- IGHV1OR21-1 | c.254C>A p.A85D | Missense Mutation (SNP) | VAF 78/672 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs764646982; called by mutect2, varscan2
- IL1RAPL2 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 43/158 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV61144728; called by muse, mutect2, varscan2
- IRX4 | c.648C>A p.D216E | Missense Mutation (SNP) | VAF 33/213 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs778606713, COSV51470989; called by muse, varscan2
- IRX6 | c.591C>A p.F197L | Missense Mutation (SNP) | VAF 68/254 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51859386; called by muse, mutect2, varscan2
- ITGAM | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.028); catalogued as COSV54934441; called by muse, mutect2, varscan2
- ITPRID1 | c.2680C>T p.L894F | Missense Mutation (SNP) | VAF 50/170 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV60070763; called by muse, mutect2, varscan2
- KAT2B | c.1622+1G>T p.X541_splice | Splice Site (SNP) | VAF 7/28 reads (25%) | catalogued as COSV55427135; called by muse, mutect2, varscan2
- KDM3B | c.1355G>A p.G452D | Missense Mutation (SNP) | VAF 58/258 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs988725742, COSV58688398; called by muse, mutect2, varscan2
- KIAA1109 | c.9907C>A p.H3303N | Missense Mutation (SNP) | VAF 67/219 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52664059; called by muse, mutect2, varscan2
- KIF2B | c.397G>T p.V133L | Missense Mutation (SNP) | VAF 76/275 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV52127518, COSV52133387; called by muse, mutect2, varscan2
- KLHL34 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1202080387, COSV65278792; called by muse, mutect2, varscan2
- KRT32 | c.843G>T p.R281S | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56785641, COSV56788097; called by muse, mutect2, varscan2
- LAX1 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as COSV65848824; called by muse, mutect2, varscan2
- LILRA6 | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.083); catalogued as COSV54430896; called by muse, mutect2, varscan2
- MAGEB3 | c.404C>A p.A135E | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.04); catalogued as COSV64396791; called by muse, mutect2, varscan2
- MAP10 | c.382T>G p.F128V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.031); catalogued as COSV69362895; called by muse, mutect2, varscan2
- MAP7D3 | c.641-1G>T p.X214_splice | Splice Site (SNP) | VAF 58/186 reads (31%) | catalogued as COSV60170195; called by muse, mutect2, varscan2
- MARCO | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 149/234 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV59052225; called by muse, mutect2, varscan2
- MAST1 | c.133A>T p.T45S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52241892; called by muse, mutect2, varscan2
- MAST1 | c.1907-1G>T p.X636_splice | Splice Site (SNP) | VAF 15/82 reads (18%) | catalogued as COSV52241916; called by muse, mutect2, varscan2
- MCM3AP | c.1579A>G p.S527G | Missense Mutation (SNP) | VAF 122/377 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV52436721; called by muse, mutect2, varscan2
- MKI67 | c.5200A>T p.K1734* | Nonsense Mutation (SNP) | VAF 60/141 reads (43%) | catalogued as COSV64072822; called by muse, mutect2, varscan2
- MTR | c.2858C>T p.P953L | Missense Mutation (SNP) | VAF 80/316 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63963997; called by muse, mutect2, varscan2
- MUC16 | c.37207G>T p.E12403* | Nonsense Mutation (SNP) | VAF 25/178 reads (14%) | catalogued as COSV67448438; called by muse, mutect2, varscan2
- MUC16 | c.16375C>A p.L5459M | Missense Mutation (SNP) | VAF 64/292 reads (22%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.003); catalogued as COSV67448443; called by muse, mutect2, varscan2
- MUC17 | c.6864C>G p.H2288Q | Missense Mutation (SNP) | VAF 140/411 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV60281556; called by muse, mutect2, varscan2
- MUC17 | c.7369C>A p.P2457T | Missense Mutation (SNP) | VAF 127/670 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1388738229, COSV60281565, COSV60289466; called by muse, mutect2, varscan2
- MYH7 | c.4004C>T p.S1335L | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as rs397516199, COSV62516785; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3B | c.1921G>T p.A641S | Missense Mutation (SNP) | VAF 60/100 reads (60%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.774); catalogued as COSV58695984; called by muse, mutect2, varscan2
- MYPN | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489529278, COSV62731883; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAV2 | c.2075C>A p.T692N (on ENST00000396087 / NM_001244963.2; = p.T669N on NM_145117.5) | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV62316435; called by muse, mutect2, varscan2
- NBPF26 | c.2637C>T p.P879= (on ENST00000620612; = p.P617= on NM_001351372.1) | Splice Region (SNP) | VAF 146/273 reads (53%) | catalogued as rs1553272258; called by muse, mutect2, varscan2
- NCKAP1L | c.2726C>A p.T909N | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV53203925; called by muse, mutect2, varscan2
- NEK4 | c.904A>T p.N302Y | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV51778966; called by muse, mutect2, varscan2
- NFATC2 | c.1489A>G p.K497E | Missense Mutation (SNP) | VAF 128/273 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65353515; called by muse, mutect2, varscan2
- NKX6-1 | c.1047C>G p.S349R | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV55684154, COSV99880191; called by muse, mutect2, varscan2
- NLGN4X | c.2129G>C p.R710P | Missense Mutation (SNP) | VAF 53/198 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as COSV52006443, COSV52018823; called by muse, mutect2, varscan2
- NLN | c.743A>G p.Y248C | Missense Mutation (SNP) | VAF 50/96 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66765079; called by muse, mutect2, varscan2
- NLRP13 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 132/236 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61620289; called by muse, mutect2, varscan2
- NOLC1 | c.469G>T p.A157S | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV64180007; called by muse, mutect2, varscan2
- NR0B1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.067); catalogued as COSV66763659; called by muse, mutect2, varscan2
- NTRK1 | c.1501+1G>T p.X501_splice | Splice Site (SNP) | VAF 53/154 reads (34%) | catalogued as COSV62323771; called by muse, mutect2, varscan2
- NUP43 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.249); catalogued as COSV61188945; called by muse, mutect2, varscan2
- OLFML2B | c.697G>T p.A233S | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV54194567; called by muse, mutect2, varscan2
- OPN5 | c.857A>T p.Q286L | Missense Mutation (SNP) | VAF 69/277 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV55244401; called by muse, mutect2, varscan2
- OPRL1 | c.488C>A p.T163K | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.999); catalogued as rs148381492, COSV61091020; called by muse, mutect2, varscan2
- OR10A4 | c.718T>G p.S240A | Missense Mutation (SNP) | VAF 31/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65841720; called by muse, mutect2, varscan2
- OR10H4 | c.430C>G p.H144D | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as COSV59061280; called by muse, mutect2, varscan2
- OR14A16 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.732); catalogued as COSV62926198; called by muse, mutect2, varscan2
- OR14I1 | c.473C>A p.T158N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61199111; called by muse, mutect2, varscan2
- OR2T2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 42/332 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373307163; called by muse, mutect2, varscan2
- OR2T2 | c.41T>G p.V14G | Missense Mutation (SNP) | VAF 43/331 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100737633, COSV61618684; called by muse, mutect2, varscan2
- OR2W3 | c.265G>T p.D89Y | Missense Mutation (SNP) | VAF 98/281 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as COSV64456197, COSV64457091, COSV64457924; called by muse, mutect2, varscan2
- OR4K15 | c.116T>A p.L39Q (on ENST00000305051; = p.L15Q on NM_001005486.1) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV59300506; called by muse, mutect2, varscan2
- OR51M1 | c.772T>A p.C258S | Missense Mutation (SNP) | VAF 58/191 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV60783900; called by muse, mutect2
- OR56A1 | c.363G>T p.M121I | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as COSV57361868; called by muse, mutect2, varscan2
- OR5H14 | c.415G>T p.G139* | Nonsense Mutation (SNP) | VAF 82/210 reads (39%) | catalogued as COSV71193484, COSV71193550; called by muse, mutect2, varscan2
- OR5T2 | c.521G>T p.S174I | Missense Mutation (SNP) | VAF 58/201 reads (29%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV57588012; called by muse, mutect2, varscan2
- OR5V1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65826589; called by muse, mutect2, varscan2
- OTUD6A | c.382G>C p.E128Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57972671; called by muse, mutect2, varscan2
- OTUD7B | c.2364G>T p.W788C | Missense Mutation (SNP) | VAF 72/297 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.416); catalogued as COSV64915314; called by muse, mutect2, varscan2
- PARVG | c.433del p.A145Pfs*30 | Frame Shift Del (DEL) | VAF 41/282 reads (15%) | catalogued as COSV63561833; called by mutect2, pindel, varscan2
- PBRM1 | c.4729G>T p.G1577C (on ENST00000296302 / NM_001366071.2; = p.G1470C on NM_018313.5) | Missense Mutation (SNP) | VAF 31/145 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV56263430, COSV56303941; called by muse, mutect2, varscan2
- PCDH19 | c.3367C>A p.H1123N (on ENST00000373034 / NM_001184880.2; = p.H1075N on NM_020766.3) | Missense Mutation (SNP) | VAF 135/442 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.025); catalogued as COSV55258331; called by muse, mutect2, varscan2
- PCDHGA2 | c.1273A>G p.K425E | Missense Mutation (SNP) | VAF 55/195 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV53906919; called by muse, mutect2, varscan2
- PCLO | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); catalogued as COSV61618634; called by muse, mutect2, varscan2
- PDE1C | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 60/243 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100371989, COSV100372115; called by muse, mutect2, varscan2
- PDE4DIP | c.6765G>T p.W2255C | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57679536; called by muse, mutect2, varscan2
- PDZD2 | c.1610G>T p.R537L | Missense Mutation (SNP) | VAF 48/264 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV56852185; called by muse, mutect2, varscan2
- PLIN3 | c.290A>G p.H97R | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as COSV55734212; called by muse, mutect2, varscan2
- PMPCB | c.47G>T p.R16L | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.018); catalogued as COSV50785576; called by muse, mutect2, varscan2
- PPIP5K2 | c.2309A>G p.E770G | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV58603075; called by muse, mutect2, varscan2
- PPP2R5B | c.722G>T p.R241L | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); catalogued as COSV51209778; called by muse, mutect2, varscan2
- PRICKLE2 | c.1124C>A p.S375Y (on ENST00000295902; = p.S319Y on NM_198859.4) | Missense Mutation (SNP) | VAF 72/387 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55763304, COSV55766376; called by muse, mutect2, varscan2
- PRICKLE3 | c.1451G>T p.G484V | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.998); catalogued as COSV66234068; called by muse, mutect2, varscan2
- PRKAA1 | c.62G>T p.R21L | Missense Mutation (SNP) | VAF 31/94 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.038); catalogued as COSV57183124; called by muse, mutect2, varscan2
- QPRT | c.785C>A p.P262Q | Missense Mutation (SNP) | VAF 87/180 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV54879186; called by muse, mutect2, varscan2
- RALGAPB | c.401G>T p.G134V | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53434876, COSV99485740; called by muse, mutect2, varscan2
- RASA2 | c.451-1G>T p.X151_splice | Splice Site (SNP) | VAF 11/31 reads (35%) | catalogued as COSV53936847, COSV53942693; called by muse, mutect2, varscan2
- RIMS2 | c.332G>C p.C111S | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68470559, COSV68477039; called by muse, mutect2, varscan2
- RIOK2 | c.737A>T p.D246V | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51611077; called by muse, mutect2, varscan2
- RMND5A | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 167/525 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV52152856; called by muse, mutect2, varscan2
- SEC24D | c.2417G>T p.R806L | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV54877271; called by muse, mutect2, varscan2
- SH3PXD2A | c.3147G>C p.Q1049H (on ENST00000369774 / NM_001365079.1; = p.Q1021H on NM_014631.2) | Missense Mutation (SNP) | VAF 142/324 reads (44%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV60115938; called by muse, mutect2, varscan2
- SIGLEC1 | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV52459462; called by muse, varscan2
- SIGLEC14 | c.604C>A p.P202T | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55777846; called by muse, mutect2, varscan2
- SLC19A1 | c.1670A>T p.E557V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV60586835; called by muse, mutect2, varscan2
- SLC30A9 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as COSV52554271; called by muse, mutect2, varscan2
- SLC7A11 | c.1379G>T p.G460V | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54928239; called by muse, mutect2, varscan2
- SMG1 | c.10868G>T p.R3623L | Missense Mutation (SNP) | VAF 217/690 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV67169680, COSV67169705; called by muse, mutect2, varscan2
- SPTA1 | c.5760del p.W1920* | Frame Shift Del (DEL) | VAF 53/202 reads (26%) | catalogued as COSV63751919; called by mutect2, pindel, varscan2
- SPTA1 | c.3322G>T p.V1108L | Missense Mutation (SNP) | VAF 50/184 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.062); catalogued as COSV63749644; called by muse, mutect2, varscan2
- SSTR4 | c.386A>T p.N129I | Missense Mutation (SNP) | VAF 204/336 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54797190; called by muse, mutect2, varscan2
- STARD8 | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs1219311104, COSV52922483; called by muse, mutect2
- STX18 | c.437G>C p.C146S | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.406); catalogued as COSV60371895; called by muse, mutect2, varscan2
- TEKT1 | c.967C>G p.R323G | Missense Mutation (SNP) | VAF 131/333 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100106125; called by muse, mutect2, varscan2
- TEKT1 | c.966C>A p.H322Q | Missense Mutation (SNP) | VAF 130/331 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV100106127; called by muse, mutect2, varscan2
- THBS2 | c.2962C>A p.L988M | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64677299; called by muse, mutect2, varscan2
- TIFAB | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 102/159 reads (64%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV72345680; called by muse, mutect2, varscan2
- TLL2 | c.1755C>A p.H585Q | Missense Mutation (SNP) | VAF 89/223 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV63571032; called by muse, mutect2, varscan2
- TLR6 | c.91G>T p.G31* | Nonsense Mutation (SNP) | VAF 76/234 reads (32%) | catalogued as COSV67935016; called by muse, mutect2, varscan2
- TMEM117 | c.991G>C p.G331R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56896173, COSV56921533; called by muse, mutect2, varscan2
- TMEM130 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.661); catalogued as rs369734825; called by muse, mutect2, varscan2
- TMPRSS12 | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 65/259 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68255845; called by muse, mutect2, varscan2
- TNFSF9 | c.727G>C p.E243Q | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.56); PolyPhen benign (0.013); catalogued as COSV55537755, COSV55537855; called by muse, mutect2, varscan2
- TNR | c.2708T>G p.V903G | Missense Mutation (SNP) | VAF 57/207 reads (28%) | SIFT tolerated (0.6); PolyPhen benign (0.192); catalogued as COSV54873045, COSV54919251; called by muse, mutect2, varscan2
- TNRC6C | c.2522G>A p.G841D | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV56941180, COSV56945531; called by muse, mutect2, varscan2
- TTN | c.47788C>T p.P15930S (on ENST00000591111; = p.P8506S on NM_003319.4) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | PolyPhen probably damaging (0.998); catalogued as COSV59910384; called by muse, mutect2
- USP11 | c.2754G>T p.E918D (on ENST00000218348; = p.E875D on NM_001371072.1) | Missense Mutation (SNP) | VAF 82/257 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.626); catalogued as COSV54472686, COSV54473254; called by muse, mutect2, varscan2
- XPO5 | c.2020G>T p.A674S | Missense Mutation (SNP) | VAF 22/387 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV54827771; called by muse, mutect2
- ZFC3H1 | c.1118A>T p.Q373L | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.452); catalogued as COSV66430538, COSV66432305; called by muse, mutect2, varscan2
- ZNF208 | c.3776G>T p.G1259V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1285650109, COSV68101522; called by muse, mutect2, varscan2
- ZNF479 | c.975C>G p.C325W | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV58636343; called by muse, mutect2, varscan2
- ZNF611 | c.1749C>G p.C583W | Missense Mutation (SNP) | VAF 202/426 reads (47%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.684); catalogued as COSV60539626, COSV60543488; called by muse, mutect2, varscan2
- GJA10 | c.1620del p.K540Nfs*? | Frame Shift Del (DEL) | VAF 9/50 reads (18%) | called by mutect2, pindel
- HS3ST3A1 | c.857T>A p.I286N | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- MAGED2 | c.1434del p.M479Wfs*5 | Frame Shift Del (DEL) | VAF 35/197 reads (18%) | called by mutect2, pindel, varscan2
- PRDM1 | c.1036dup p.S346Kfs*78 | Frame Shift Ins (INS) | VAF 42/218 reads (19%) | called by mutect2, pindel, varscan2
- RBM10 | c.1891dup p.A631Gfs*42 | Frame Shift Ins (INS) | VAF 26/97 reads (27%) | called by mutect2, pindel, varscan2
- SYNE2 | c.4911_4913del p.Y1638del | In Frame Del (DEL) | VAF 49/220 reads (22%) | called by mutect2, pindel, varscan2
- ABCA5 | c.858A>G p.T286= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV67015912; called by muse, mutect2, varscan2
- ATP2B2 | c.2994C>T p.N998= (on ENST00000352432; = p.N964= on NM_001683.5) | Silent (SNP) | VAF 44/234 reads (19%) | catalogued as rs759463804, COSV59490670; called by muse, mutect2, varscan2
- AVPR2 | c.495C>A p.A165= | Silent (SNP) | VAF 41/137 reads (30%) | catalogued as COSV61685846; called by muse, mutect2, varscan2
- C10orf53 | c.228C>A p.T76= | Silent (SNP) | VAF 52/165 reads (32%) | catalogued as COSV65108493; called by muse, mutect2, varscan2
- CACNA1E | c.420G>A p.G140= | Silent (SNP) | VAF 182/601 reads (30%) | catalogued as COSV62383938; called by muse, mutect2, varscan2
- CAPN6 | c.480T>C p.N160= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as COSV60694028; called by muse, mutect2, varscan2
- CCDC198 | c.99T>C p.F33= | Silent (SNP) | VAF 39/154 reads (25%) | catalogued as COSV53601451; called by muse, mutect2, varscan2
- CDC42EP1 | c.693C>T p.P231= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs1190859443, COSV50755680; called by muse, mutect2, varscan2
- CDH23 | c.306C>A p.T102= | Silent (SNP) | VAF 73/228 reads (32%) | catalogued as COSV54925852; called by muse, mutect2, varscan2
- CHD5 | c.1339C>T p.L447= | Silent (SNP) | VAF 119/183 reads (65%) | catalogued as COSV52408983; called by muse, mutect2, varscan2
- COG5 | c.1650G>T p.V550= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV51743635; called by muse, mutect2, varscan2
- CPS1 | c.2199A>G p.P733= | Silent (SNP) | VAF 66/109 reads (61%) | catalogued as rs780079490, COSV51803421; called by muse, mutect2, varscan2
- CREB3L3 | c.789G>A p.K263= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs745478008, COSV50175016; called by muse, varscan2
- CSMD2 | c.891C>T p.R297= | Silent (SNP) | VAF 127/205 reads (62%) | catalogued as rs143306375; called by muse, mutect2, varscan2
- CSMD3 | c.627C>T p.I209= | Silent (SNP) | VAF 30/192 reads (16%) | catalogued as COSV52113674; called by muse, mutect2
- CT83 | c.189T>C p.S63= | Silent (SNP) | VAF 93/272 reads (34%) | catalogued as COSV64140810; called by muse, mutect2, varscan2
- DDX49 | c.645C>T p.T215= | Silent (SNP) | VAF 25/108 reads (23%) | catalogued as rs776218879, COSV53229646; called by muse, mutect2, varscan2
- ENO3 | c.342G>T p.V114= | Silent (SNP) | VAF 148/305 reads (49%) | catalogued as COSV56697277; called by muse, mutect2, varscan2
- F8 | c.3672C>A p.I1224= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV64270131; called by muse, mutect2, varscan2
- FADS6 | c.744G>T p.L248= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV59601618; called by muse, mutect2, varscan2
- FAT3 | c.13311C>A p.S4437= | Silent (SNP) | VAF 19/53 reads (36%) | catalogued as COSV53081326; called by muse, mutect2, varscan2
- FLNC | c.7434C>A p.I2478= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV57951454; called by muse, mutect2, varscan2
- FOXP2 | c.555G>A p.Q185= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs1017119086, COSV63481978; called by muse, mutect2, varscan2
- GOLIM4 | c.2070A>G p.S690= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as COSV58328184; called by muse, mutect2, varscan2
- GRIN3A | c.3024C>A p.P1008= | Silent (SNP) | VAF 68/156 reads (44%) | catalogued as COSV62451310; called by muse, mutect2, varscan2
- HAUS4 | c.180A>G p.L60= | Silent (SNP) | VAF 102/276 reads (37%) | catalogued as COSV52826805, COSV52826907; called by muse, mutect2, varscan2
- HEG1 | c.2469C>T p.S823= | Silent (SNP) | VAF 86/270 reads (32%) | catalogued as COSV60759854; called by muse, mutect2, varscan2
- HERC2 | c.8964A>G p.T2988= | Silent (SNP) | VAF 74/196 reads (38%) | catalogued as rs1019855385, COSV55310351; called by muse, mutect2, varscan2
- IGSF10 | c.3699G>A p.V1233= | Silent (SNP) | VAF 90/246 reads (37%) | catalogued as rs557184605, COSV56782197; called by muse, mutect2, varscan2
- IHH | c.990C>T p.A330= | Silent (SNP) | VAF 69/113 reads (61%) | catalogued as COSV55392810; called by muse, mutect2, varscan2
- IP6K2 | c.876C>T p.F292= | Silent (SNP) | VAF 34/228 reads (15%) | catalogued as COSV53659940; called by muse, mutect2, varscan2
- KRT3 | c.300C>A p.G100= | Silent (SNP) | VAF 71/212 reads (33%) | catalogued as COSV58814817; called by muse, mutect2, varscan2
- KRT85 | c.141G>A p.G47= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV57736101; called by muse, mutect2, varscan2
- MAGEA12 | c.927T>C p.F309= | Silent (SNP) | VAF 145/453 reads (32%) | catalogued as COSV63294248; called by muse, mutect2, varscan2
- MAGEE1 | c.201C>T p.S67= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV63909010; called by muse, mutect2
- MED24 | c.225C>T p.Y75= | Silent (SNP) | VAF 43/162 reads (27%) | catalogued as rs748538779, COSV62417415; called by muse, mutect2, varscan2
- NEU3 | c.387G>A p.K129= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV53635769; called by muse, mutect2, varscan2
- NIBAN3 | c.342G>T p.R114= | Silent (SNP) | VAF 36/159 reads (23%) | catalogued as COSV56305765; called by muse, mutect2, varscan2
- NRK | c.4107T>C p.Y1369= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV54590957; called by muse, mutect2, varscan2
- NUTM1 | c.2517T>C p.G839= | Silent (SNP) | VAF 16/128 reads (13%) | catalogued as COSV59215925; called by muse, mutect2, varscan2
- OCA2 | c.48G>T p.A16= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV62339720; called by muse, mutect2, varscan2
- OGDHL | c.2487C>T p.R829= | Silent (SNP) | VAF 70/405 reads (17%) | catalogued as rs770634118, COSV65101229; called by muse, varscan2
- OR2T10 | c.12C>A p.A4= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV57896231; called by muse, mutect2, varscan2
- OR4C6 | c.393G>C p.T131= | Silent (SNP) | VAF 39/167 reads (23%) | catalogued as COSV58602697, COSV58605476; called by muse, mutect2, varscan2
- OR51V1 | c.117C>A p.A39= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as rs1353950865, COSV58314272; called by muse, mutect2, varscan2
- OR52A1 | c.345C>T p.G115= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV100200456, COSV61092033; called by muse, mutect2, varscan2
- PDE1C | c.1329G>T p.T443= | Silent (SNP) | VAF 60/242 reads (25%) | catalogued as COSV100372120, COSV58512533; called by muse, mutect2, varscan2
- POLE | c.387A>G p.A129= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV57675062; called by muse, mutect2, varscan2
- RHEBL1 | c.6G>T p.P2= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as COSV56504051; called by muse, mutect2, varscan2
- SIMC1 | c.2172C>A p.I724= (on ENST00000443967 / NM_001308196.1; = p.I309= on NM_198567.5) | Silent (SNP) | VAF 215/315 reads (68%) | catalogued as COSV57900500; called by muse, mutect2, varscan2
- SLC9A1 | c.2005C>A p.R669= | Silent (SNP) | VAF 58/83 reads (70%) | catalogued as COSV56051487; called by muse, mutect2, varscan2
- SLIT3 | c.3882C>A p.G1294= | Silent (SNP) | VAF 25/40 reads (63%) | catalogued as COSV60594728, COSV60595306; called by muse, mutect2, varscan2
- SZT2 | c.7464T>C p.G2488= (on ENST00000634258 / NM_001365999.1; = p.G2431= on NM_015284.4) | Silent (SNP) | VAF 206/315 reads (65%) | catalogued as COSV65167638; called by muse, mutect2, varscan2
- WRAP53 | c.495C>T p.S165= | Silent (SNP) | VAF 63/137 reads (46%) | catalogued as rs147817526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZDHHC9 | c.378C>T p.I126= | Silent (SNP) | VAF 36/586 reads (6%) | catalogued as COSV64096193; called by muse, mutect2
- AC092718.9 | chr16:81154099 G>C | 3'Flank (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
- AMFR | c.*323C>A | 3'UTR (SNP) | VAF 45/174 reads (26%) | catalogued as COSV99315797; called by muse, mutect2, varscan2
- CDKL1 | n.55G>C | RNA (SNP) | VAF 40/124 reads (32%) | called by muse, mutect2, varscan2
- IGKV1OR22-5 | n.19C>T | RNA (SNP) | VAF 39/157 reads (25%) | called by muse, mutect2, varscan2
- LINC01565 | n.1284A>G | RNA (SNP) | VAF 76/232 reads (33%) | called by muse, mutect2, varscan2
- OBSCN | c.11660-1809A>G | Intron (SNP) | VAF 39/143 reads (27%) | catalogued as COSV99476355; called by muse, mutect2, varscan2
- OBSCN | c.18662-2046C>G | Intron (SNP) | VAF 22/53 reads (42%) | catalogued as COSV99476356; called by muse, mutect2, varscan2
- RPGR | c.2520+1236A>G | Intron (SNP) | VAF 19/48 reads (40%) | catalogued as rs1324920665, COSV58832871; called by muse, mutect2, varscan2
- SPRR2D | c.-1G>A | 5'UTR (SNP) | VAF 83/277 reads (30%) | catalogued as COSV64209043; called by muse, mutect2, varscan2
